Gene-level copy-number profile of tumor specimen TARGET-40-PAUTWB-01A from TARGET case TARGET-40-PAUTWB, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 13.9 years (5,064 days).
Specimen TARGET-40-PAUTWB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.352752e9-758c-57bd-a5ac-69036d020b78.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PAUTWB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 400 have no estimate.
https://portal.gdc.cancer.gov/files/0c90bcf8-743c-4e1a-b7bd-6478bb7ceb4d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,380; copy number 1: 14,847; copy number 2: 38,526; copy number 3: 2,000; copy number 4: 754; copy number 5: 818; copy number 7: 25; copy number 8: 284; copy number 9: 62; copy number 10: 499; copy number 11: 28.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,645,902–117,027,039, 8 genes: BZW1P2, TUSC7, AC108713.1, MIR4447, AC069504.1, LINC00901, RNU5E-8P, PTMAP8.
- chr9:21,802,636–22,128,103, 14 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,716 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 1 gene, copy number 7 (within-gene range 2–7): AC244205.1.
- chr2:88,857,161–89,117,844, 24 genes, copy number 7: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17.
- chr6:39,039,603–53,236,297, 306 genes, copy number 8–11 (broad region; genes not listed).
- chr8:46,028,804–55,081,909, 135 genes, copy number 5 (broad region; genes not listed).
- chr8:55,135,203–55,142,358, 1 gene, copy number 5: AC022679.2.
- chr8:67,952,046–87,615,219, 295 genes, copy number 5 (within-gene range 4–12) (broad region; genes not listed).
- chr8:87,575,598–87,576,508, 1 gene, copy number 11: VTA1P2.
- chr8:103,500,696–104,256,094, 1 gene, copy number 5 (within-gene range 4–5): RIMS2.
- chr8:103,768,281–138,497,261, 386 genes, copy number 5 (broad region; genes not listed).
- chr17:7,686,071–27,003,259, 566 genes, copy number 8–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 14,824. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
